Somatic mutation profile of tumor specimen MP2PRT-PAVXWF-TMP1-A (aliquot MP2PRT-PAVXWF-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVXWF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (917 days).
Specimen MP2PRT-PAVXWF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 724a9c37-ace7-4794-833b-1ce38b9637d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXWF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXWF-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a0aa55e-c53a-49d9-8d7b-322ae7ef3460

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.4794G>A p.W1598* | Nonsense Mutation (SNP) | VAF 22/286 reads (8%) | catalogued as COSV62413727, COSV62420417; called by muse, mutect2
- CHD4 | c.2935C>T p.R979* (on ENST00000357008 / NM_001363606.2; = p.R992* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 32/316 reads (10%) | catalogued as COSV58902179, COSV58908525; called by muse, mutect2, varscan2
- DLX5 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 44/672 reads (7%) | catalogued as COSV56033490; called by muse, mutect2
- FASN | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as rs200927634, COSV60750921; called by muse, mutect2
- NR3C2 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1403371155, COSV60985894; called by muse, mutect2
- PTPN3 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 32/399 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as rs539842793; called by muse, mutect2
- ZNF92 | c.809C>T p.S270L (on ENST00000328747 / NM_152626.4; = p.S201L on NM_007139.4) | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV60875105; called by muse, mutect2
- ARFGEF1 | c.4826C>T p.P1609L | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- CFAP54 | c.5836G>C p.D1946H | Missense Mutation (SNP) | VAF 31/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRFIP2 | c.1256G>C p.R419T | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MROH2B | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.082); called by muse, mutect2
- SNX4 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- SOWAHD | c.799A>T p.R267W | Missense Mutation (SNP) | VAF 66/818 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- BRSK2 | c.1911C>T p.H637= | Silent (SNP) | VAF 99/681 reads (15%) | catalogued as rs772305366, COSV57543076; called by muse, mutect2, varscan2
- CYFIP1 | c.1870C>A p.R624= | Silent (SNP) | VAF 50/633 reads (8%) | catalogued as CM142910; called by muse, mutect2
- PTPN23 | c.2580C>A p.L860= | Silent (SNP) | VAF 75/750 reads (10%) | called by muse, mutect2, varscan2
- REXO1 | c.3555C>T p.L1185= | Silent (SNP) | VAF 24/314 reads (8%) | catalogued as COSV99402755; called by muse, mutect2
- SPDYE4 | c.549C>T p.L183= | Silent (SNP) | VAF 30/393 reads (8%) | called by muse, mutect2
- SSTR5 | c.519G>A p.P173= | Silent (SNP) | VAF 80/850 reads (9%) | catalogued as rs768486571, COSV99559491; called by muse, mutect2
- SYT7 | c.915C>T p.Y305= | Silent (SNP) | VAF 37/287 reads (13%) | catalogued as rs759041073, COSV55653902, COSV55660189; called by muse, mutect2, varscan2
